Gene-level copy-number profile of tumor specimen HTMCP-03-06-02392-01A from CGCI case HTMCP-03-06-02392, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.0 years (22,269 days).
Specimen HTMCP-03-06-02392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ad3c9722-b31e-4527-b8c3-a591ed1d7041.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02392-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/2d883328-482d-40c9-9412-a9995f91eb9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 12,407; copy number 2: 36,053; copy number 3: 9,676; copy number 4: 83; copy number 5: 4; copy number 6: 8; copy number 11: 34; copy number 13: 1; copy number 14: 7; copy number 20: 5.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:41,859,350–41,899,253, 3 genes (within-gene range 0–1): ATP6V0E1P2, Y_RNA, U8.
- chr3:60,616,822–60,856,605, 6 genes (within-gene range 0–1): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr4:86,336,318–86,336,614, 1 gene (within-gene range 0–1): RN7SKP96.
- chr12:83,151,331–92,363,832, 94 genes (broad region; genes not listed).
- chr13:37,534,940–37,551,536, 1 gene: LINC00547.
- chr15:65,381,484–65,517,704, 5 genes (within-gene range 0–1): IGDCC4, DPP8, AC105129.3, AC105129.1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,934,286, 8 genes, copy number 6: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr11:32,602,246–35,020,591, 49 genes, copy number 5–20 (within-gene range 1–20): CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, HIPK3, KIAA1549L, AL137161.1, AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343.
- chr12:92,420,094–92,431,002, 2 genes, copy number 5 (within-gene range 2–5): CLLU1-AS1, CLLU1.

Autosomal genes at a single copy (total copy number 1): 10,063. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
